Somatic mutation profile of tumor specimen MP2PRT-PATXKD-TMP1-A (aliquot MP2PRT-PATXKD-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATXKD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,284 days).
Specimen MP2PRT-PATXKD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2581f8c0-0ac2-4214-9f15-da4b88615984.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATXKD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATXKD-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d9e51cc-b2a1-4462-8e71-9da922fa345d

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, In Frame Ins 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBLIM1 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 162/390 reads (42%) | catalogued as rs772093436, COSV60030960, COSV60031768; called by muse, varscan2
- GRID2 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 111/267 reads (42%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.621); catalogued as rs575224950, COSV56230200; called by muse, mutect2, varscan2
- MAGEL2 | c.3131C>T p.S1044L | Missense Mutation (SNP) | VAF 157/364 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1267004913; called by muse, mutect2, varscan2
- MPP6 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 137/382 reads (36%) | catalogued as COSV99757837; called by muse, mutect2, varscan2
- PDGFA | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 160/326 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140399739; called by mutect2, varscan2
- CLSTN1 | c.2373_2374insGATAAG p.K791_L792insDK (on ENST00000377298 / NM_001009566.3; = p.K781_L782insDK on NM_014944.4) | In Frame Ins (INS) | VAF 94/338 reads (28%) | called by mutect2, varscan2
- ETV6 | c.1070_1071insAAGGCC p.F357delinsLRP | In Frame Ins (INS) | VAF 122/387 reads (32%) | called by mutect2, pindel, varscan2
- TM6SF1 | c.931T>C p.S311P | Missense Mutation (SNP) | VAF 111/260 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ZBTB7A | c.644_645insGGGG p.N215Kfs*36 | Frame Shift Ins (INS) | VAF 570/725 reads (79%) | called by mutect2, pindel, varscan2
- FSCN1 | c.894C>T p.I298= | Silent (SNP) | VAF 30/594 reads (5%) | catalogued as rs147410388; called by muse, mutect2
- MCC | c.1705C>T p.L569= | Silent (SNP) | VAF 143/343 reads (42%) | called by muse, mutect2, varscan2
- TMEM132C | c.2694C>T p.H898= | Silent (SNP) | VAF 225/529 reads (43%) | catalogued as rs951252351; called by muse, mutect2, varscan2
